Surgical pathology report (de-identified scan), TCGA case TCGA-AR-A24M, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Mayo, specimen TCGA-AR-A24M-01A (Primary Tumor).

Final Diagnosis

Breast, left, wide local excision: Invasive mammary carcinoma with mixed ductal and lobular features, Nottingham grade II (of III), forming a 2.5 x 2.4 x 2.2 cm mass (AJCC pT2). The surgical resection margins are negative for tumor. A fibroadenoma (0.9 x 0.8 x 0.6 cm) is also identified.

Lymph nodes, left axillary sentinel, excision: Left axillary sentinel lymph nodes No. 1 and No. 2 are positive for metastatic mammary carcinoma. Left axillary sentinel lymph node No. 3 is negative for tumor. Blue dye is identified in all three left axillary sentinel lymph nodes.

Lymph node, left axillary, excision: A single left axillary lymph node is negative for tumor.

Lymph nodes, left axillary, dissection: Multiple (2 of 24) left axillary lymph nodes are positive for tumor (AJCC pN2).

Her-2/Neu has been ordered on paraffin embedded tissue.

1CD-0-3

carcinoma, infiltrating duct and lobular 8522/3

Site: breast, NOS C50.9

hw
4/25/11

Source: NCI Genomic Data Commons file 401f8626-d5e7-45b8-b6de-8ab91ed3732c (TCGA-AR-A24M.56DFBCCE-A9D9-4F08-AC7E-33998F3439B2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).